Somatic mutation profile of tumor specimen TCGA-55-7574-01A (aliquot TCGA-55-7574-01A-11D-2036-08) from TCGA case TCGA-55-7574, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.9 years (23,703 days).
Specimen TCGA-55-7574-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 876e80f1-3c84-4649-b922-493d3f894786.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7574-10A (Blood Derived Normal), aliquot TCGA-55-7574-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6675f6b0-85f2-4520-aa9a-b1701b23736a

The open-access MAF lists 235 somatic variants for this specimen: 188 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 44, Nonsense Mutation 15, Frame Shift Del 2, Splice Region 2, RNA 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs1567542019, CM123558, COSV52688134, COSV99393932; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.099); catalogued as COSV52747494; called by muse, mutect2
- ABCG4 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV56642768; called by muse, mutect2
- ABLIM3 | c.1892G>A p.R631K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58648084; called by muse, mutect2
- ADCK2 | c.1699A>C p.S567R | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs561363159, COSV50783383; called by muse, mutect2
- ADGRB3 | c.3792G>T p.E1264D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV53258690; called by muse, mutect2, varscan2
- ADGRV1 | c.6574G>C p.D2192H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315773, COSV67994341; called by muse, mutect2
- AFF2 | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54005729; called by muse, mutect2, varscan2
- ALG13 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52639162; called by muse, mutect2
- ANK2 | c.5138A>T p.K1713I | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV52185543; called by muse, mutect2
- ANKRD30A | c.647G>A p.G216E (on ENST00000611781; = p.G160E on NM_052997.2) | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100654523, COSV64619253; called by muse, mutect2
- AP002748.5 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs759486291, COSV59151509; called by muse, mutect2
- AR | c.1659C>G p.Y553* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV65963675; called by muse, mutect2
- ARFGEF2 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.227); catalogued as COSV64214825; called by muse, mutect2
- ARHGAP39 | c.2492G>T p.R831L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52775333, COSV99430098; called by muse, mutect2, varscan2
- ASB3 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV55079694; called by muse, mutect2, varscan2
- ASXL2 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs780638285, COSV55458245; called by muse, mutect2
- ATAD5 | c.3937G>A p.E1313K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58978461; called by muse, mutect2
- ATF2 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV51374778; called by muse, mutect2
- ATP11C | c.2888C>A p.T963K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV59573137; called by muse, mutect2, varscan2
- ATP13A5 | c.709T>A p.S237T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60874735; called by muse, mutect2, varscan2
- ATP1B4 | c.1027G>A p.D343N (on ENST00000218008 / NM_001142447.3; = p.D339N on NM_012069.5) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54314478, COSV99486544; called by muse, mutect2
- BAHCC1 | c.1695G>C p.K565N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV57032760; called by muse, mutect2
- BDP1 | c.2878A>T p.T960S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV62434378; called by muse, mutect2, varscan2
- BOD1L1 | c.1880C>G p.P627R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV50057451; called by muse, mutect2, varscan2
- BTBD10 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53400344; called by muse, mutect2
- BTBD9 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58435155; called by muse, mutect2
- C10orf53 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV65108664; called by muse, mutect2
- C1QTNF9 | c.965C>A p.T322K | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1459241480, COSV59658115; called by muse, mutect2
- C5orf15 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV51549031; called by muse, mutect2
- CACNA1S | c.5189C>A p.A1730E | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100755194; called by muse, mutect2, varscan2
- CADPS2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV57383358; called by muse, mutect2
- CAMSAP2 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV52676653; called by muse, mutect2, varscan2
- CCBE1 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67950286, COSV67951393; called by muse, mutect2, varscan2
- CCL16 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.363); catalogued as rs775901091; called by muse, mutect2
- CD93 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV55668260; called by muse, mutect2
- CDH10 | c.1476C>A p.F492L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV52595608; called by muse, mutect2, varscan2
- CERS4 | c.912C>G p.F304L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV52170304; called by muse, mutect2
- CHD1L | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.462); catalogued as COSV63615274; called by muse, mutect2
- CLCN3 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV61628423; called by muse, mutect2
- CNR1 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV62990986; called by muse, mutect2, varscan2
- CNTRL | c.4420G>C p.E1474Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV53052870; called by muse, mutect2
- COL27A1 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs1320994477, COSV61930364; called by muse, mutect2
- COL2A1 | c.2806G>A p.G936S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777615798, COSV61528699; called by muse, mutect2, varscan2
- CSNK2A1 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV53937416; called by muse, mutect2
- CYP4A11 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV60225401; called by muse, mutect2
- DAPK3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1184011576, COSV56664675; called by muse, mutect2, varscan2
- DBF4B | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.864); catalogued as COSV59259713, COSV59263360; called by muse, mutect2
- DCAF12L1 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV64422219; called by muse, mutect2, varscan2
- DCLRE1A | c.1857G>C p.E619D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV63749630; called by muse, mutect2, varscan2
- DDX4 | c.1142T>A p.I381N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737642; called by muse, mutect2
- DNAAF3 | c.1429G>C p.D477H (on ENST00000524407 / NM_001256715.2; = p.D524H on NM_178837.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1448187041, COSV61279260; called by muse, mutect2, varscan2
- DNAH7 | c.6240G>T p.M2080I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs769474761, COSV56783391, COSV56794633; called by muse, mutect2, varscan2
- EFCAB6 | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as COSV53058689; called by muse, mutect2
- ELF2 | c.784G>A p.E262K (on ENST00000379550 / NM_001331036.2; = p.E202K on NM_006874.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55495437; called by muse, mutect2
- EPHA3 | c.155G>A p.W52* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV60719833, COSV60725206; called by muse, mutect2
- EPHA8 | c.1084T>C p.Y362H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV51293908; called by muse, mutect2
- EPHB1 | c.1168del p.R390Afs*58 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as COSV67673023; called by mutect2, pindel, varscan2
- EPPK1 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV73262331; called by muse, mutect2
- ESRRB | c.620A>T p.K207M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV55062946, COSV55066615; called by muse, mutect2
- F8 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.173); catalogued as COSV64276654, COSV64278110; called by muse, mutect2
- FAT3 | c.824C>A p.S275* | Nonsense Mutation (SNP) | VAF 13/120 reads (11%) | catalogued as COSV53167409, COSV53172293; called by muse, mutect2, varscan2
- FAT4 | c.3429G>C p.Q1143H | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV67898642; called by muse, mutect2
- FERMT2 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58409161; called by muse, mutect2, varscan2
- FIGN | c.30G>C p.L10F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60771433; called by muse, mutect2
- FLG | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 41/646 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs777352352, COSV64248125; called by muse, mutect2
- FSD2 | c.35A>C p.D12A | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); catalogued as COSV58012457; called by muse, mutect2
- GABRE | c.720G>T p.W240C | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64821161; called by muse, mutect2
- GAN | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV73721340; called by muse, mutect2
- GHITM | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs778618042, COSV64539174; called by muse, varscan2
- GPR148 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV59309365; called by muse, mutect2, varscan2
- GPT | c.255C>G p.V85= | Splice Region (SNP) | VAF 34/388 reads (9%) | catalogued as COSV52954716; called by muse, mutect2
- HELZ | c.5201C>G p.S1734C | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.286); catalogued as COSV62380663; called by muse, mutect2
- HMGCLL1 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV51451241; called by muse, mutect2
- HSF2 | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63774497; called by muse, mutect2, varscan2
- HSPA12B | c.400G>C p.A134P | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54768896; called by muse, mutect2
- HUWE1 | c.4348C>A p.L1450I | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs782159467, COSV53362432; called by muse, mutect2
- HYOU1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV68215546, COSV68217240; called by muse, mutect2, varscan2
- IFI6 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100191388, COSV59269956; called by muse, mutect2, varscan2
- IFT122 | c.2026G>C p.E676Q (on ENST00000348417 / NM_052989.3; = p.E617Q on NM_018262.4) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as COSV56206170; called by muse, mutect2
- IGKV1-9 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 23/250 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs200429819; called by muse, mutect2
- INSRR | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV63876930; called by muse, mutect2, varscan2
- JAK1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61094121, COSV61094364; called by muse, mutect2
- KCNA4 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV60252040, COSV60255677; called by muse, mutect2, varscan2
- KCNA4 | c.386A>C p.E129A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV60255686; called by muse, mutect2, varscan2
- KCNU1 | c.2177C>G p.S726* | Nonsense Mutation (SNP) | VAF 37/295 reads (13%) | catalogued as COSV67753202; called by muse, mutect2, varscan2
- KCTD19 | c.2487C>A p.D829E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58574842; called by muse, mutect2
- KRTAP26-1 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV62129278; called by muse, mutect2, varscan2
- LCT | c.5381C>T p.A1794V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs183725992; called by muse, mutect2
- LDOC1 | c.212C>G p.T71R | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65159109, COSV65159655; called by muse, mutect2
- LRP1 | c.9040C>T p.R3014C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as rs1206981394, COSV54524565; called by muse, mutect2, varscan2
- LRP1B | c.3305C>A p.S1102Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV101258331, COSV67264925; called by muse, mutect2, varscan2
- LRP2 | c.9410G>C p.C3137S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55571523; called by muse, mutect2
- LRRC4C | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537158, COSV99538994; called by muse, mutect2, varscan2
- LRRC4C | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53432061; called by muse, mutect2, varscan2
- LRRC8C | c.2275G>A p.V759I | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65000834; called by muse, mutect2
- LZTS1 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99743140; called by mutect2, varscan2
- MANEA | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62590462; called by muse, mutect2, varscan2
- MARCO | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV59058148; called by muse, mutect2, varscan2
- MBOAT2 | c.969G>C p.L323F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60010549; called by muse, mutect2, varscan2
- MEGF8 | c.2338A>C p.T780P (on ENST00000251268 / NM_001271938.2; = p.T713P on NM_001410.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV52099839; called by muse, mutect2, varscan2
- MID2 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); catalogued as COSV53313601; called by muse, mutect2
- MRPS22 | c.187G>C p.E63Q (on ENST00000310776 / NM_001363893.1; = p.E64Q on NM_020191.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60351179; called by muse, mutect2
- MUC4 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.866); catalogued as COSV62189862; called by muse, mutect2
- MUC4 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.374); catalogued as rs1054616127, COSV62125615; called by muse, mutect2
- MUC4 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 6/174 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV62189896; called by muse, mutect2
- MYH1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs201260086, COSV55440101; called by muse, mutect2, varscan2
- MYPN | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV62732038, COSV62738558; called by muse, mutect2, varscan2
- NAXD | c.1136A>T p.D379V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV57288854; called by muse, mutect2, varscan2
- NGEF | c.1907C>A p.A636D | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50952198; called by muse, mutect2, varscan2
- NID1 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV51628194; called by muse, mutect2, varscan2
- NUP98 | c.2706G>C p.K902N | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61437857; called by muse, mutect2
- OR10R2 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100936813; called by muse, mutect2
- OR10Z1 | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100779027, COSV63526287; called by muse, mutect2, varscan2
- OR2J3 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV101013557, COSV65849366; called by muse, mutect2
- OR2L13 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV63560184; called by muse, mutect2, varscan2
- OR4A5 | c.752G>T p.C251F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60524492; called by muse, mutect2, varscan2
- OR52E8 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV66207668, COSV66211831; called by muse, mutect2, varscan2
- OR5B21 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs748974135, COSV64482230; called by mutect2, varscan2
- OR5J2 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as COSV56623012; called by muse, mutect2
- OR7G1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1223651049, COSV53318893, COSV53319270; called by muse, mutect2
- OR7G2 | c.600T>A p.C200* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV59688920; called by muse, mutect2, varscan2
- P2RY10 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV50685480; called by muse, mutect2, varscan2
- PACS1 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as rs773415096, COSV57699713; called by muse, mutect2, varscan2
- PAK5 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as COSV62036837; called by muse, mutect2
- PARP2 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV51641922; called by muse, mutect2, varscan2
- PCDHB14 | c.838A>T p.T280S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV53391011; called by muse, mutect2
- PCDHB3 | c.1213T>A p.S405T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50627175; called by muse, mutect2, varscan2
- PCDHGA1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1198878768, COSV65299227; called by muse, mutect2, varscan2
- PCNX2 | c.4412G>T p.G1471V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV50874530; called by muse, mutect2
- PDE3B | c.2461C>A p.H821N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56390065; called by muse, mutect2, varscan2
- PDZD2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56871363, COSV56874154; called by muse, mutect2
- PFKL | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV62465354; called by muse, mutect2, varscan2
- PHF24 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV99646176; called by muse, mutect2
- PKLR | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV61362405, COSV61362446; called by muse, mutect2
- PLCL1 | c.2326C>G p.P776A | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70871044; called by muse, mutect2
- PLEKHG5 | c.2495C>T p.S832F (on ENST00000400915 / NM_001042663.3; = p.S795F on NM_020631.6) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV61069548; called by muse, mutect2, varscan2
- PLG | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 20/127 reads (16%) | catalogued as COSV51985439, COSV51986146; called by muse, mutect2, varscan2
- PRAM1 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.13); catalogued as COSV55316862; called by muse, mutect2, varscan2
- PRDM9 | c.1794C>A p.H598Q | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57012498; called by muse, mutect2
- PRKCH | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV60651765; called by muse, mutect2, varscan2
- PRUNE2 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV65029403; called by muse, mutect2
- RAPGEF3 | c.2452C>T p.L818F (on ENST00000389212; = p.L776F on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV50234713; called by muse, mutect2, varscan2
- RASAL2 | c.1427C>G p.S476* | Nonsense Mutation (SNP) | VAF 11/243 reads (5%) | catalogued as COSV62722129; called by muse, mutect2
- RFC5 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs376942205; called by muse, mutect2
- RLIM | c.1230G>C p.M410I | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV60328840; called by muse, mutect2
- RNF169 | c.1990C>T p.Q664* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV55135420; called by muse, mutect2
- RP1L1 | c.3218G>T p.R1073L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as COSV66753696, COSV66754580; called by muse, mutect2, varscan2
- RUSC1 | c.549C>A p.N183K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV52741168, COSV52742366; called by muse, mutect2
- RYR3 | c.14194G>C p.E4732Q (on ENST00000389232; = p.E4733Q on NM_001036.6) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV66806807; called by muse, mutect2
- SDK2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs199755742, COSV66195588; called by muse, mutect2, varscan2
- SEC14L5 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV52041620; called by muse, mutect2, varscan2
- SEMA5B | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52107089; called by muse, mutect2
- SEPTIN4 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as COSV58728988; called by muse, mutect2
- SH3TC2 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV60467434; called by muse, mutect2, varscan2
- SIPA1L2 | c.2747G>C p.R916T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1346612881, COSV53398824; called by muse, mutect2
- SIRT7 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489157032, COSV60816102; called by mutect2, varscan2
- SLC25A2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs782676413, COSV53403488; called by muse, mutect2, varscan2
- SLC2A9 | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV53327814; called by muse, mutect2, varscan2
- SMARCA1 | c.2989C>T p.Q997* | Nonsense Mutation (SNP) | VAF 5/81 reads (6%) | catalogued as COSV64413625; called by muse, mutect2
- SNX15 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100101284; called by muse, varscan2
- SOD1 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM930678, COSV54257117; called by muse, mutect2, varscan2
- SRGAP1 | c.675A>G p.R225= | Splice Region (SNP) | VAF 4/27 reads (15%) | catalogued as COSV61902860; called by muse, mutect2
- SV2C | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV59228104; called by muse, mutect2, varscan2
- SYNJ2 | c.1965G>C p.K655N | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62900541; called by muse, mutect2
- TAFA1 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV72040780; called by muse, mutect2, varscan2
- TARS2 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60874983; called by muse, mutect2
- TECTA | c.5038G>T p.V1680L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV50795338; called by muse, mutect2
- TG | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313276149, COSV55092470; called by muse, mutect2, varscan2
- THAP9 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV56357256, COSV56357741; called by muse, mutect2
- TM2D1 | c.14G>C p.W5S | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); catalogued as COSV53909072, COSV53909231; called by muse, mutect2
- TNS4 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 24/420 reads (6%) | catalogued as COSV54187768; called by muse, mutect2
- TREM2 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as COSV58295649; called by muse, mutect2
- TRIML1 | c.1073G>T p.C358F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60196692; called by muse, mutect2, varscan2
- TRIP13 | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV51321780; called by muse, mutect2, varscan2
- TRIR | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV54407609; called by muse, mutect2, varscan2
- TRRAP | c.3431G>C p.R1144P | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62852686, COSV62853378; called by muse, mutect2
- TTN | c.19183G>A p.D6395N (on ENST00000591111; = p.D5468N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | PolyPhen benign (0.046); catalogued as CD121841, COSV60311066; called by muse, mutect2, varscan2
- UGT1A5 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV59397291; called by muse, mutect2
- USP26 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.91); catalogued as COSV63709667; called by muse, mutect2, varscan2
- WDFY3 | c.2056C>T p.H686Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV55712697; called by muse, mutect2, varscan2
- WNK1 | c.6442C>T p.L2148F (on ENST00000315939 / NM_018979.4; = p.L1900F on NM_014823.3) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV60044111; called by muse, mutect2
- ZKSCAN1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.966); catalogued as rs1416332243, COSV60875544; called by muse, mutect2
- ZNF41 | c.2259G>C p.Q753H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV57445000; called by muse, mutect2, varscan2
- ZNF526 | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.236); catalogued as COSV55900766; called by muse, mutect2, varscan2
- C17orf50 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- OR4E2 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF585A | c.1080del p.K361Rfs*9 (on ENST00000292841 / NM_001288800.2; = p.K306Rfs*9 on NM_152655.3) | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, varscan2
- ADCY9 | c.1255C>T p.L419= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV53581162; called by muse, mutect2, varscan2
- ADGRF5 | c.2715C>G p.L905= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV51939519; called by muse, mutect2, varscan2
- AL645922.1 | c.1047C>G p.V349= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs773084699, COSV100191301; called by muse, mutect2
- ATP6V0A2 | c.1989C>T p.L663= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs1196490909, COSV57751979; called by muse, mutect2, varscan2
- BICC1 | c.2250G>A p.E750= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1220534991, COSV54066700; called by muse, mutect2, varscan2
- BSN | c.8679G>A p.V2893= | Silent (SNP) | VAF 22/174 reads (13%) | catalogued as COSV99609159; called by muse, mutect2
- CAPN13 | c.1353G>T p.L451= | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as COSV54434894; called by muse, mutect2, varscan2
- CARM1 | c.1800G>A p.P600= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as rs763545329, COSV53403060; called by muse, mutect2
- CD180 | c.813C>G p.L271= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV56519613, COSV99842332; called by muse, mutect2
- CENPE | c.1776G>A p.K592= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV54389059; called by muse, mutect2, varscan2
- CLPB | c.249C>G p.L83= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV53628020, COSV53632212, COSV99577898; called by muse, mutect2, varscan2
- COL13A1 | c.2016G>A p.K672= (on ENST00000398978 / NM_001130103.2; = p.K600= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV62567664; called by muse, mutect2
- CYP4F3 | c.762G>A p.Q254= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as COSV55413352; called by muse, mutect2, varscan2
- DDX4 | c.1140G>A p.Q380= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV61757049; called by muse, mutect2
- GABRE | c.882C>G p.L294= | Silent (SNP) | VAF 7/125 reads (6%) | catalogued as rs1183286263, COSV64821152; called by muse, mutect2
- GNA12 | c.882C>T p.F294= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1307023091, COSV51745074; called by muse, mutect2
- GPRIN1 | c.1335G>T p.V445= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV56144534; called by muse, mutect2
- IGSF9B | c.2370C>T p.L790= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV58072303; called by muse, mutect2
- LRP1B | c.3306C>A p.S1102= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101258330; called by muse, mutect2, varscan2
- MGLL | c.442C>T p.L148= (on ENST00000398104 / NM_001003794.2; = p.L158= on NM_007283.6) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV54026990; called by muse, mutect2
- MYOF | c.3507C>G p.L1169= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100826204, COSV63710065; called by muse, mutect2
- MYOM3 | c.2553C>T p.V851= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV58400279; called by muse, mutect2
- NEK3 | c.1482G>A p.L494= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1382618921, COSV51619083; called by muse, mutect2
- OR14C36 | c.558T>G p.S186= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs777691603, COSV58602671; called by muse, mutect2, varscan2
- OR2G6 | c.382C>A p.R128= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV58575716; called by muse, mutect2, varscan2
- OR5L1 | c.420G>T p.V140= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs750272765, COSV61735277; called by muse, mutect2, varscan2
- OSCP1 | c.720A>T p.A240= (on ENST00000356637 / NM_001330493.1; = p.A230= on NM_145047.5) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV52487006; called by muse, mutect2, varscan2
- POTEF | c.99C>T p.P33= | Silent (SNP) | VAF 30/308 reads (10%) | catalogued as COSV62543902; called by muse, mutect2
- SEC24C | c.1441C>T p.L481= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV59544674; called by muse, mutect2, varscan2
- SEMA6C | c.2136C>T p.L712= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV59007305; called by muse, mutect2, varscan2
- SLC8A1 | c.1665C>A p.I555= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV60483302, COSV60495041; called by muse, mutect2
- SPATA32 | c.402G>C p.R134= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV59304842; called by muse, mutect2
- SSU72 | c.189G>A p.Q63= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV52218996; called by muse, mutect2
- TAGAP | c.2088C>A p.T696= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV57853017; called by muse, mutect2, varscan2
- TCF20 | c.5634G>T p.A1878= | Silent (SNP) | VAF 6/131 reads (5%) | catalogued as rs763222374, COSV59491725, COSV59495669; called by muse, mutect2
- TTLL4 | c.549C>G p.L183= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV51439109; called by muse, mutect2
- TTYH3 | c.1179C>T p.L393= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV51862858; called by muse, mutect2, varscan2
- U2AF2 | c.873C>G p.V291= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV58276170; called by muse, mutect2, varscan2
- UAP1 | c.1005A>T p.V335= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV54853445; called by muse, mutect2
- VSIG4 | c.237G>A p.Q79= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV66074874; called by muse, mutect2, varscan2
- ZBTB12 | c.78C>T p.L26= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV64994156; called by muse, mutect2
- ZNF248 | c.1074G>C p.G358= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV61998494; called by muse, mutect2, varscan2
- ZNF521 | c.3384G>A p.E1128= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV64131398; called by muse, mutect2, varscan2
- ZNF592 | c.3405G>A p.S1135= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1216802801, COSV55439379; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185121C>T | Intron (SNP) | VAF 8/130 reads (6%) | catalogued as rs1347157111, COSV100302565; called by muse, mutect2
- SSPOP | n.15549G>T | RNA (SNP) | VAF 5/30 reads (17%) | catalogued as COSV65136468; called by muse, mutect2, varscan2
- WNK2 | chr9:93318448 G>A | 3'Flank (SNP) | VAF 10/106 reads (9%) | catalogued as rs1215267701, COSV52958793; called by muse, mutect2
